Gene-level copy-number profile of tumor specimen TARGET-40-PATMPU-01A from TARGET case TARGET-40-PATMPU, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 13.9 years (5,060 days).
Specimen TARGET-40-PATMPU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-OS.ceba6667-9602-5c10-9320-298d95e354e5.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-40-PATMPU-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 409 have no estimate.
https://portal.gdc.cancer.gov/files/7d792ab9-c37e-4b4f-8849-25b1d2ec6f11

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2,659; copy number 1: 2,387; copy number 2: 23,053; copy number 3: 21,610; copy number 4: 4,053; copy number 5: 4,404; copy number 6: 1,360; copy number 7: 318; copy number 8: 208; copy number 9: 32; copy number 10: 12; copy number 11: 27; copy number 12: 30; copy number 13: 21; copy number 15: 13; copy number 16: 1; copy number 17: 6; copy number 19: 18; copy number 20: 2.

Homozygous deletions (total copy number 0; autosomes only): 68 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:25,242,249–25,338,213, 1 gene (within-gene range 0–4): RSRP1.
- chr1:25,266,102–25,330,445, 3 genes: AL031432.2, RHD, SDHDP6.
- chr3:11,745–54,346, 2 genes: LINC01986, AC066595.1.
- chr3:29,054,570–29,290,726, 2 genes (within-gene range 0–2): RBMS3-AS3, MESTP4.
- chr4:53,286–576,295, 22 genes: ZNF595, AC253576.1, ZNF718, AC253576.2, AC108475.1, ZNF876P, AC079140.3, AC079140.5, ZNF732, AC079140.6, AC079140.4, ZNF141, AC079140.1, AC079140.2, MIR571, AC092574.2, ZNF519P4, AC092574.1, ABCA11P, ZNF721, PIGG, TMEM271.
- chr4:31,997,376–32,353,220, 3 genes: LINC02506, AC097654.1, LINC02353.
- chr4:36,496,128–36,641,939, 1 gene (within-gene range 0–1): LINC02505.
- chr4:38,966,744–39,182,258, 4 genes (within-gene range 0–11): TMEM156, KLHL5, AC079921.1, AC079921.2.
- chr4:46,243,548–46,724,408, 4 genes (within-gene range 0–2): GABRA2, AC095060.1, RNU6-412P, RAC1P2.
- chr4:189,764,391–189,940,733, 1 gene (within-gene range 0–2): FRG1-DT.
- chr6:101,430,411–101,431,553, 1 gene: ACTG1P18.
- chr6:119,159,297–119,159,476, 1 gene: AL022722.2.
- chr7:147,080,934–147,097,609, 1 gene: CNTNAP2-AS1.
- chr11:84,545,131–84,640,565, 2 genes: HNRNPA1P72, AP000852.1.
- chr14:79,072,132–79,074,767, 1 gene: AC026888.1.
- chr16:10,214,784–10,227,581, 2 genes: AC022168.1, RN7SL493P.
- chr19:94,062–344,815, 17 genes (within-gene range 0–2): OR4G3P, OR4G1P, OR4F17, WBP1LP11, OR4F8P, AC092192.1, SEPTIN14P19, CICP19, AC092299.1, AC010507.1, LINC01002, AC010507.2, RNU6-1076P, AC016588.2, PLPP2, MIER2, AC016588.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 6,452 genes in 72 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:2,315,040–3,955,262, 59 genes, copy number 5: AL590822.3, MORN1, AL589739.1, AL513477.1, AL513477.2, RER1, PEX10, PLCH2, AL139246.1, AL139246.4, PANK4, HES5, AL139246.5, TNFRSF14-AS1, TNFRSF14, AL139246.2, AL139246.3, PRXL2B, MMEL1, MMEL1-AS1, TTC34, AC242022.2, AC242022.1, AL592464.2, AL592464.3, AL592464.1, AL589702.1, ACTRT2, PRDM16-DT, PRDM16, MIR4251, AL008733.1, AL512383.1, AL590438.1, AL354743.2, AL354743.1, ARHGEF16, AL512413.1, MEGF6, MIR551A, AL513320.1, TPRG1L, WRAP73, TP73, TP73-AS3, TP73-AS2, TP73-AS1, AL136528.1, CCDC27, SMIM1, LRRC47, RN7SL574P, AL365330.1, CEP104, DFFB, C1orf174, LINC01134, LINC01346, LINC01345.
- chr1:71,081,324–73,749,623, 19 genes, copy number 6 (within-gene range 3–6): ZRANB2-AS2, AL358453.1, NEGR1, AL354949.1, AL359821.1, NEGR1-IT1, GDI2P2, AL513166.1, RPL31P12, AL583808.1, RNU6-1246P, LINC02796, LINC02797, AL732618.1, KRT8P21, RN7SKP19, LINC01360, LINC02238, RNA5SP50.
- chr1:74,469,376–111,320,566, 603 genes, copy number 5–6 (within-gene range 3–10) (broad region; genes not listed).
- chr1:112,466,541–116,166,241, 86 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr1:116,493,016–121,580,524, 119 genes, copy number 5 (broad region; genes not listed).
- chr1:193,473,224–206,464,443, 266 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr2:88,857,161–96,811,874, 208 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr2:105,744,912–106,477,669, 17 genes, copy number 5: NCK2, AC010978.1, AC009505.1, ECRG4, UXS1, AC018878.1, AC092106.1, RPL22P10, SRSF3P4, RPS21P2, RPL27AP4, ILRUNP1, AC114755.1, ANAPC1P6, PLGLA, RGPD3, AC097527.1.
- chr2:114,420,125–119,700,151, 46 genes, copy number 5–11: RNU2-41P, DPP10, DPP10-AS3, DPP10-AS2, AC093610.1, DPP10-AS1, RPSAP23, AC016721.1, AC104408.1, AC062016.1, MTCYBP39, AC062016.2, MTND1P28, MTND2P21, MTCO1P43, RNU7-190P, AC092170.1, AC064856.1, AC009312.1, DDX18, AC009404.1, HTR5BP, CCDC93, AC009303.1, AC009303.2, AC009303.3, AC009303.4, RN7SL111P, INSIG2, THORLNC, LINC01956, EN1, MARCO, AC013457.1, C1QL2, RN7SL468P, STEAP3, STEAP3-AS1, C2orf76, DBI, TMEM37, SCTR, SCTR-AS1, CFAP221, TMEM177, RPL17P15.
- chr2:120,346,136–126,118,023, 46 genes, copy number 5–10: INHBB, LINC01101, AC073257.2, AC073257.1, Y_RNA, AC018866.1, GLI2, AC017033.1, Y_RNA, AC067960.1, AC079988.1, TFCP2L1, RPS17P7, CLASP1, AC012447.1, RNU4ATAC, Y_RNA, NIFK-AS1, RPL12P15, AC018737.2, NPM1P32, NIFK, TSN, AC018737.1, LINC01823, AC011246.1, AC073632.1, AC062020.1, LINC01826, AC073409.2, AC073409.1, ELOAP1, PSMD14P1, AC064859.1, RN7SKP102, AC079154.1, CNTNAP5, MTND5P22, AC019159.2, AC019159.1, RNA5SP102, RNU6-259P, AC097499.2, LINC01889, AC097499.1, LINC01941.
- chr2:187,712,816–190,371,665, 37 genes, copy number 5–7 (within-gene range 4–7): LINC01090, ST13P2, AC104131.1, RNA5SP114, GULP1, MIR561, AC092598.1, DIRC1, COL3A1, MIR1245A, MIR1245B, MIR3606, COL5A2, AC133106.1, MIR3129, KRT18P19, WDR75, KDM3AP1, AC013439.1, SLC40A1, AC012488.1, ASNSD1, ASDURF, AC012488.2, ANKAR, OSGEPL1, OSGEPL1-AS1, AC013468.1, ORMDL1, PMS1, C2orf88, TERF1P6, HNRNPCP2, RNF11P1, MSTN, HIBCH, INPP1.
- chr2:193,170,704–205,798,133, 221 genes, copy number 5–7 (broad region; genes not listed).
- chr2:214,411,054–216,206,303, 30 genes, copy number 5 (within-gene range 4–5): VWC2L, VWC2L-IT1, ENSAP3, BARD1, SNHG31, SNORA70I, RPL10P6, ABCA12, AC072062.1, AC092844.1, LINC02862, ATIC, FN1, AC012462.3, AC012462.1, AC012462.2, AC012668.2, AC012668.3, AC012668.1, LINC00607, LINC01614, AC093850.1, AC122136.1, AC093382.1, MREG, PECR, TMEM169, XRCC5, POLHP1, AC012513.2.
- chr2:216,590,426–223,398,546, 171 genes, copy number 5 (broad region; genes not listed).
- chr4:24,517,441–25,418,498, 17 genes, copy number 11: DHX15, MIR573, RN7SL16P, ATP5MGP3, LINC02473, AC006390.1, HNRNPA1P65, SOD3, CCDC149, LGI2, SEPSECS, SEPSECS-AS1, PI4K2B, AC104662.1, U2, ZCCHC4, ANAPC4.
- chr4:40,020,240–40,377,513, 13 genes, copy number 15: KRT18P25, AC098591.2, N4BP2, RNU6-1112P, AC098591.1, AC095057.1, AC095057.3, AC095057.4, RHOH, AC095057.2, LINC02265, CHRNA9, RNU7-74P.
- chr4:41,842,154–42,707,335, 18 genes, copy number 12–17: HMGB1P28, LINC00682, AC108210.1, AC108210.2, TMEM33, DCAF4L1, AC106052.1, SLC30A9, ATP1B1P1, BEND4, AC111006.1, AC024022.1, SHISA3, ATP8A1, RPS7P7, CCNL2P1, AC096734.2, AC096734.1.
- chr4:48,805,212–92,304,178, 659 genes, copy number 5–8 (broad region; genes not listed).
- chr4:132,435,802–158,278,676, 385 genes, copy number 5–7 (broad region; genes not listed).
- chr5:16,373,361–20,937,800, 76 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr5:51,886,688–54,645,987, 38 genes, copy number 5–8: RNA5SP182, KATNBL1P4, AC091903.1, LINC02118, RPS17P11, MFSD4BP1, AC022126.1, PELO, ITGA1, AC022133.2, B3GNTL1P1, AC022133.1, AC025180.1, ITGA2, AC008966.3, AC008966.2, MOCS2, AC008966.1, AC026477.1, AC027329.1, AC108114.1, FST, NDUFS4, LINC02105, ASS1P9, AC025175.1, ARL15, AC025175.2, RNU6-272P, MIR581, RN7SL801P, AC016601.1, AC008873.1, LINC01033, RPL37P25, HSPB3, SNX18, AC016583.1.
- chr6:38,675,925–55,940,624, 354 genes, copy number 5–9 (broad region; genes not listed).
- chr9:12,685,439–21,059,323, 108 genes, copy number 6–7 (broad region; genes not listed).
- chr9:23,826,491–27,543,902, 36 genes, copy number 6–7 (within-gene range 3–7): AL161628.1, AL365204.1, AL365204.2, AL365204.3, AL513317.1, IZUMO3, AL353811.1, RMRPP5, RN7SKP120, AL353730.1, TUSC1, LINC01241, FAM71BP1, AL353753.1, AL442639.1, AL451137.2, AL451137.1, AL356133.1, CAAP1, H3P31, RN7SL100P, PLAA, IFT74, IFT74-AS1, LRRC19, AL355432.1, TEK, RNA5SP280, AL355433.1, LINC00032, EQTN, MOB3B, AL163192.1, AL451123.2, IFNK, AL451123.1.
- chr9:28,888,879–36,022,113, 205 genes, copy number 6 (broad region; genes not listed).
- chr9:38,392,702–41,701,096, 104 genes, copy number 5 (broad region; genes not listed).
- chr10:133,420,666–133,642,894, 14 genes, copy number 5: SPRN, OR6L2P, SCART1, OR7M1P, CYP2E1, AL161645.1, AL161645.2, SYCE1, AL731769.2, OR6L1P, AL731769.1, FRG2B, RARRES2P2, AGGF1P2.
- chr11:76,591,023–80,528,066, 70 genes, copy number 5 (broad region; genes not listed).
- chr11:84,936,689–90,226,538, 136 genes, copy number 5 (broad region; genes not listed).
- chr11:124,115,404–129,895,590, 145 genes, copy number 6 (broad region; genes not listed).
- chr11:130,666,735–134,505,665, 51 genes, copy number 6 (within-gene range 4–6): MIR8052, LINC02873, AP003486.2, PPP1R10P1, LINC02551, SNX19, AP003486.1, RN7SL167P, AP002856.3, AP002856.1, AP002856.4, AP002856.2, NTM, RNU6ATAC12P, AP003025.1, AP003025.2, NTM-AS1, AP004372.1, AP000844.2, AP000844.1, NTM-IT, AP000843.1, OPCML, U6, AP003784.1, OPCML-IT2, AP004782.1, AP003972.1, OPCML-IT1, AP004606.1, LINC02743, SPATA19, AP001979.1, IGSF9B, MIR4697, LINC02730, LINC02731, AP000911.1, JAM3, PTP4A2P2, NCAPD3, AP001775.1, AP001775.2, VPS26B, THYN1, ACAD8, GLB1L3, AP000859.1, GLB1L2, B3GAT1, B3GAT1-DT.
- chr14:97,110,416–106,235,594, 434 genes, copy number 6–8 (broad region; genes not listed).
- chr15:77,041,404–101,933,350, 632 genes, copy number 5–7 (broad region; genes not listed).
- chr17:9,822,206–18,414,380, 251 genes, copy number 5 (broad region; genes not listed).
- chr17:18,537,800–21,002,276, 152 genes, copy number 5–8 (within-gene range 1–8) (broad region; genes not listed).
- chr19:27,638,483–29,715,789, 49 genes, copy number 6–19: ERVK-28, AC112702.1, LINC00662, AC006504.1, AC006504.5, AC006504.7, AC006504.3, SLC25A1P5, AC006504.2, AC006504.4, AC005357.2, AC006504.6, AC005758.1, AC005357.1, AC010511.1, AC020905.1, AC005580.1, AC093074.1, AC005307.1, AC005394.2, AC005381.1, AC005394.1, AC005616.1, AC079466.2, AC079466.1, AC005524.1, MAN1A2P1, AC007795.1, LINC00906, AC008991.1, AC011524.1, AC011524.2, RNA5SP470, LINC01532, AC011505.1, UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12.
- chr19:51,914,675–52,242,440, 21 genes, copy number 13: AC011460.1, ZNF613, ZNF350-AS1, ZNF350, ZNF615, ZNF614, ZNF432, AC011468.5, AC011468.1, ZNF841, AC011468.4, ZNF616, AC011468.2, AC011468.3, RPL37P23, ZNF836, AC010320.1, PPP2R1A, MIR6801, AC010320.2, AC010320.5.
- chr20:87,250–1,393,164, 42 genes, copy number 5: DEFB125, DEFB126, DEFB127, DEFB128, DEFB129, DEFB132, AL034548.1, C20orf96, ZCCHC3, AL034548.2, NRSN2-AS1, SOX12, NRSN2, TRIB3, RBCK1, TBC1D20, Y_RNA, CSNK2A1, TCF15, SRXN1, AL121758.1, SCRT2, SLC52A3, FAM110A, RPS10P5, ANGPT4, RSPO4, AL110114.1, PSMF1, ACTG1P3, TMEM74B, AL031665.1, C20orf202, RAD21L1, SNPH, SDCBP2, AL136531.2, AL136531.3, SDCBP2-AS1, AL136531.1, FKBP1A, MIR6869.
- chr20:26,167,817–33,111,751, 113 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr22:19,291,969–23,547,797, 307 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,346. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
